Somatic mutation profile of tumor specimen TCGA-AP-A0LS-01A (aliquot TCGA-AP-A0LS-01A-11D-A14G-09) from TCGA case TCGA-AP-A0LS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.3 years (23,126 days).
Specimen TCGA-AP-A0LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a2503b4-8cc5-4975-812c-5d2cc8a03fc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LS-10B (Blood Derived Normal), aliquot TCGA-AP-A0LS-10B-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c32ee117-12f7-49af-af88-4a98e9a4d5ea

The open-access MAF lists 504 somatic variants for this specimen: 392 protein-altering or splice-affecting, 105 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 105, Frame Shift Del 97, Frame Shift Ins 18, Nonsense Mutation 8, Splice Site 7, Intron 4, Splice Region 4, In Frame Del 2, RNA 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 29/64 reads (45%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 22/47 reads (47%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs397514495, CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.600-1G>A p.X200_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as rs45517117, CS992719, COSV54756054, COSV99552886; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.10359G>T p.L3453F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV101446839; called by muse, mutect2, varscan2
- AC011448.1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99364389; called by muse, mutect2, varscan2
- AC098582.1 | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV99985340; called by muse, mutect2, varscan2
- ACP5 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs529545521, COSV54536834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSL6 | c.1160G>A p.R387H (on ENST00000379240; = p.R412H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs571229269, COSV99732835; called by muse, mutect2, varscan2
- ACTA1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100796704; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAMTS6 | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66860327, COSV66864284; called by muse, mutect2
- ADCY6 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100326422; called by muse, mutect2, varscan2
- AGGF1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs772593663, COSV100461563; called by muse, mutect2, varscan2
- AKAP11 | c.5639T>C p.V1880A | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99213585; called by muse, mutect2, varscan2
- ALMS1 | c.6493G>A p.A2165T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV100041349; called by muse, mutect2, varscan2
- AMBRA1 | c.2254C>T p.R752C (on ENST00000458649 / NM_001367468.1; = p.R662C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs774527865, COSV100092958; called by muse, mutect2, varscan2
- AMER2 | c.1853T>C p.L618P | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as COSV100766150; called by muse, mutect2, varscan2
- ANP32A | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51189534, COSV99142980; called by muse, mutect2, varscan2
- ANXA9 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs753432922, COSV64484835; called by muse, mutect2, varscan2
- AP1B1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58018819; called by muse, mutect2, varscan2
- AP4B1 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV99870602; called by muse, mutect2, varscan2
- APMAP | c.945del p.Y316Tfs*29 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs777444320; called by mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGEF2 | c.2125A>G p.N709D (on ENST00000361247 / NM_001162383.2; = p.N681D on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.824); catalogued as COSV100560119; called by muse, mutect2, varscan2
- ARID4B | c.1125T>G p.N375K | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935107; called by muse, mutect2, varscan2
- ARL1 | c.389T>C p.M130T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV99880284; called by muse, varscan2
- ARMH4 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs765276741, COSV99957725; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATG2A | c.5225C>A p.P1742H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs781243276, COSV101033920; called by muse, mutect2, varscan2
- ATP2A1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100706848; called by muse, mutect2, varscan2
- ATP2B3 | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99683238; called by muse, mutect2, varscan2
- ATP7B | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs761147984, CM087673, COSV54438958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B4 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV99464059; called by muse, mutect2, varscan2
- BAZ2A | c.3225G>T p.E1075D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV99464861; called by muse, mutect2, varscan2
- BBOF1 | c.1355T>C p.L452S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100620818; called by muse, mutect2, varscan2
- BEX5 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV100375000; called by muse, mutect2, varscan2
- C1QTNF6 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs1270622432, COSV99742180; called by muse, mutect2, varscan2
- C8orf74 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as COSV100261685; called by muse, varscan2
- CACNA1A | c.1898T>C p.M633T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100801250; called by muse, mutect2, varscan2
- CACNB1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757223702, COSV100703321; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CAPN11 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101291849; called by muse, mutect2, varscan2
- CAPN5 | c.1102G>A p.E368K (on ENST00000456580; = p.E328K on NM_004055.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1052408892, COSV99581818; called by muse, mutect2, varscan2
- CASC3 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as COSV99229529; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC71 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV100422293; called by muse, mutect2, varscan2
- CCDC73 | c.3192del p.R1066Efs*13 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs1356986265, COSV58794814; called by mutect2, pindel, varscan2
- CCNB1 | c.21+2T>C p.X7_splice | Splice Site (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99841218; called by muse, mutect2, varscan2
- CCT6A | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99303248; called by muse, mutect2, varscan2
- CDC45 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs746919823, COSV99596473; called by muse, mutect2, varscan2
- CDH19 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100050979; called by muse, mutect2, varscan2
- CDT1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs1327591000, COSV99967082; called by muse, mutect2, varscan2
- CEP170B | c.584G>A p.R195H (on ENST00000453495; = p.R124H on NM_015005.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1485048064, COSV101371411; called by muse, mutect2, varscan2
- CFAP46 | c.6493C>T p.P2165S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs560086678, COSV99583847; called by muse, mutect2, varscan2
- CHMP1A | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs771909969, COSV99498271; called by muse, mutect2, varscan2
- CHMP7 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100500518; called by muse, mutect2, varscan2
- CHRND | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51317381, COSV99285465; called by muse, mutect2, varscan2
- CLDN11 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV50355802; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNNM4 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100998606, COSV65661905; called by muse, mutect2, varscan2
- COL11A2 | c.2756G>C p.G919A (on ENST00000341947 / NM_080680.3; = p.G812A on NM_080679.2) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100553513; called by muse, mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL4A5 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100086718, COSV60359519; called by muse, mutect2, varscan2
- COQ8B | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs758779701, COSV54685165; called by muse, mutect2, varscan2
- CPB2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99472975; called by muse, mutect2, varscan2
- CPXCR1 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99342005; called by muse, mutect2, varscan2
- CRNKL1 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371503092; called by muse, mutect2, varscan2
- CROCC | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100978079; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CUBN | c.9280G>A p.D3094N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs765436466, COSV100912166; called by muse, mutect2, varscan2
- CYP11B2 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.574); catalogued as COSV100010742; called by muse, mutect2, varscan2
- DBP | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99320515; called by muse, mutect2, varscan2
- DCANP1 | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101538216; called by muse, mutect2, varscan2
- DDIAS | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100231045; called by muse, mutect2, varscan2
- DGKD | c.796C>T p.R266C (on ENST00000264057 / NM_152879.3; = p.R222C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs954861746, COSV99895556; called by muse, mutect2, varscan2
- DHX37 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs769322775, COSV100439032; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DOP1B | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99535757; called by muse, mutect2, varscan2
- DSCAML1 | c.1105C>A p.L369I (on ENST00000321322; = p.L309I on NM_020693.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100354850; called by muse, mutect2
- DSTYK | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100904483; called by muse, mutect2, varscan2
- DYNC2H1 | c.12199C>T p.R4067* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs376596919; called by muse, mutect2, varscan2
- DYRK1A | c.968A>C p.Q323P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100117537; called by muse, mutect2, varscan2
- EFEMP1 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100816751; called by muse, mutect2, varscan2
- EFR3A | c.664_666del p.S222del | In Frame Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs753653319; called by mutect2, pindel, varscan2
- EHMT2 | c.2825A>G p.D942G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99998656; called by muse, mutect2, varscan2
- ELAPOR1 | c.1947+2T>C p.X649_splice | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100884409; called by muse, mutect2, varscan2
- EP400 | c.2297T>C p.L766P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100200573; called by muse, mutect2, varscan2
- EPB41L4B | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766696614, COSV101000861; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | catalogued as rs771807343; called by mutect2, varscan2
- EPHB6 | c.2548A>G p.I850V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100844152; called by muse, mutect2, varscan2
- EPN3 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369357861; called by muse, mutect2, varscan2
- ERC2 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV99881725; called by muse, mutect2, varscan2
- ESR2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs565210086, COSV99962873; called by muse, mutect2, varscan2
- EYS | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.243); catalogued as COSV100675786; called by muse, mutect2, varscan2
- FADS6 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894196807, COSV100043981; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | catalogued as rs748967872; called by mutect2, varscan2
- FBXL20 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs371836119; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FCHO2 | c.900del p.D301Mfs*13 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV55111559; called by mutect2, pindel, varscan2
- FLNC | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100367687; called by muse, mutect2, varscan2
- FMO4 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100882029; called by muse, mutect2
- FOLR3 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100281740; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD3 | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs772647620, COSV99345759; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs756304971; called by mutect2, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 16/31 reads (52%) | catalogued as rs755581817; called by mutect2, varscan2
- GABRG2 | c.365A>C p.Y122S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100729591; called by muse, mutect2, varscan2
- GAL3ST1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58892717; called by muse, mutect2, varscan2
- GALR3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.186); catalogued as COSV50764365; called by muse, mutect2, varscan2
- GHSR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.054); catalogued as rs1177771500, COSV53840233; called by muse, mutect2, varscan2
- GLYATL2 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.883); catalogued as COSV99780229; called by muse, mutect2, varscan2
- GORASP1 | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV100072980; called by muse, mutect2, varscan2
- GP9 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs983071890, CM1410131, COSV100264607; called by muse, mutect2, varscan2
- GPAT3 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100022788; called by muse, mutect2, varscan2
- GPR158 | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100892934; called by muse, mutect2, varscan2
- GPR65 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.562); catalogued as COSV50862401; called by muse, mutect2, varscan2
- GRIN2D | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99615973; called by muse, mutect2, varscan2
- GRIN3B | c.1920del p.T641Rfs*6 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs1265788787; called by mutect2, pindel, varscan2
- GRM4 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV100945829; called by muse, mutect2, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- HCN1 | c.1736T>C p.M579T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100298878, COSV100302536; called by muse, mutect2, varscan2
- HEATR1 | c.4862A>G p.D1621G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV63979726; called by muse, mutect2, varscan2
- HEXIM1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100203397; called by muse, mutect2, varscan2
- HK1 | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100065633; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs767148651; called by mutect2, varscan2
- HPS1 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756794900, COSV100282379; called by muse, mutect2, varscan2
- HR | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs747380523, COSV57190869; called by muse, mutect2, varscan2
- HRG | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs149578094; called by muse, mutect2, varscan2
- HSP90B1 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as COSV100236338; called by muse, mutect2, varscan2
- IFNA5 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1250557025, COSV99423639, COSV99423801; called by muse, mutect2, varscan2
- IFT74 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs1471659921, COSV101197129; called by muse, mutect2, varscan2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs760021495; called by mutect2, varscan2
- IKZF5 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64397813; called by muse, mutect2, varscan2
- IMPDH2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs1419998470, COSV100454947; called by muse, mutect2
- INCENP | c.2104C>T p.R702W (on ENST00000394818 / NM_001040694.2; = p.R698W on NM_020238.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs533741220, COSV99610728; called by muse, varscan2
- IPO4 | c.3080G>A p.C1027Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100268888; called by muse, mutect2, varscan2
- IRAG1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV101350952; called by muse, mutect2, varscan2
- IRGQ | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV60670952; called by muse, mutect2, varscan2
- ISYNA1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs200357380, COSV99525982; called by muse, mutect2, varscan2
- JUP | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.316); catalogued as COSV100159363, COSV100159666; called by muse, mutect2, varscan2
- KANSL1 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV52264743; called by muse, mutect2, varscan2
- KBTBD3 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV101595669; called by muse, mutect2, varscan2
- KCNQ4 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs772979020, COSV100714289; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIF7 | c.1640dup p.R549Afs*40 | Frame Shift Ins (INS) | VAF 28/58 reads (48%) | catalogued as rs770571299; called by mutect2, varscan2
- KLF3 | c.654del p.L219* | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs1260051731; called by mutect2, pindel, varscan2
- KLHL36 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs762545271, COSV50718231; called by muse, mutect2, varscan2
- KRT1 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1565646239, COSV99358518; called by muse, mutect2
- KRT74 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV99977408; called by muse, mutect2, varscan2
- LACC1 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as COSV100354623; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as rs1406609727; called by mutect2, pindel, varscan2
- LMTK3 | c.4131del p.E1378Rfs*106 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs758225154; called by mutect2, varscan2
- LONRF3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0.241); catalogued as COSV100504247; called by muse, mutect2, varscan2
- LPXN | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs761885239, COSV101222963, COSV67717421; called by muse, mutect2, varscan2
- LRCH2 | c.1749T>G p.S583R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.944); catalogued as COSV100406409; called by muse, mutect2, varscan2
- LRCH2 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1393376673, COSV100406412; called by muse, mutect2, varscan2
- LYN | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319577; called by muse, mutect2, varscan2
- MAGEE2 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs774700498, COSV64897174; called by muse, mutect2, varscan2
- MAN1B1 | c.1014dup p.L339Afs*18 | Frame Shift Ins (INS) | VAF 26/59 reads (44%) | catalogued as rs752359237; called by mutect2, varscan2
- MAP7 | c.69A>G p.A23= | Splice Region (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100643768; called by muse, mutect2
- MAPK8IP1 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs759515254, COSV53797223; called by muse, varscan2
- MAZ | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs923278394, COSV50715678; called by muse, mutect2, varscan2
- MED15 | c.935A>C p.Q312P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.871); catalogued as COSV99487409; called by muse, mutect2, varscan2
- MFSD6L | c.1040A>C p.Q347P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100266179; called by muse, mutect2, varscan2
- MGA | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99578763; called by muse, mutect2
- MGAT4A | c.889+2T>C p.X297_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99383992; called by muse, mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 30/60 reads (50%) | catalogued as rs546807245; called by mutect2, varscan2
- MLNR | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.557); catalogued as rs1362328067, COSV99519693; called by muse, mutect2, varscan2
- MMP12 | c.18A>G p.I6M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV100404831; called by muse, mutect2, varscan2
- MON2 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753049786, COSV54815342, COSV99741773; called by muse, mutect2, varscan2
- MRFAP1L1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV100299025; called by muse, mutect2, varscan2
- MTAP | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV101205408; called by muse, mutect2, varscan2
- MUC16 | c.18658T>G p.S6220A | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV101198407; called by muse, mutect2, varscan2
- MYBL1 | c.1606A>C p.N536H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101576485; called by mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs760302326; called by mutect2, varscan2
- MYOM1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs780023288, COSV99865541; called by muse, mutect2, varscan2
- MYOM2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV100036806; called by muse, mutect2, varscan2
- NAA35 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV100863300; called by muse, mutect2, varscan2
- NAALAD2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as rs1353345421, COSV100428101; called by muse, mutect2, varscan2
- NAP1L3 | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV59074386; called by muse, mutect2, varscan2
- NCF4 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1438774544, COSV99957121; called by muse, mutect2, varscan2
- NFKBIL1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.203); catalogued as rs973490545, COSV101092863; called by muse, mutect2, varscan2
- NKX2-2 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101010514; called by muse, mutect2, varscan2
- NLRX1 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.777); catalogued as COSV99423839; called by muse, mutect2, varscan2
- NOL11 | c.1315G>T p.G439* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99474868; called by muse, mutect2, varscan2
- NOSIP | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV100182149; called by mutect2, varscan2
- NOTCH1 | c.3563T>C p.L1188P | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as COSV99485834; called by muse, mutect2, varscan2
- NOX1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs192653247, COSV54193235; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs760102115; called by mutect2, varscan2
- NUDCD3 | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs775577561, COSV100622011; called by muse, mutect2, varscan2
- OR2AG2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs200936147; called by muse, mutect2, varscan2
- OR2C1 | c.38T>A p.V13D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV100514863, COSV100514981; called by muse, mutect2, varscan2
- OR9A4 | c.535del p.C179Vfs*23 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs562194466; called by mutect2, varscan2
- OTOGL | c.1352C>T p.A451V (on ENST00000547103; = p.A442V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as COSV101509029; called by muse, mutect2, varscan2
- PAPPA2 | c.690G>C p.R230S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.041); catalogued as COSV100866531, COSV100866580; called by muse, mutect2, varscan2
- PCDHA6 | c.2128C>A p.L710M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100971271; called by muse, mutect2, varscan2
- PCDHGA6 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs759357506, COSV53933095; called by muse, mutect2, varscan2
- PDE3B | c.2843A>G p.H948R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962079; called by muse, mutect2, varscan2
- PFKL | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100827010; called by muse, mutect2, varscan2
- PHF13 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV50011318; called by muse, mutect2, varscan2
- PIK3CA | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55932192, COSV55944790; called by muse, mutect2, varscan2
- PIK3CG | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100782596; called by muse, mutect2, varscan2
- PKD2L1 | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100559306; called by muse, mutect2, varscan2
- PLAGL1 | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394168; called by muse, mutect2, varscan2
- PLEC | c.9634C>T p.R3212W (on ENST00000322810 / NM_201380.4; = p.R3102W on NM_000445.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs376638828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PODXL2 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351164950, COSV99229617; called by muse, mutect2, varscan2
- POGLUT3 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs370467268; called by muse, mutect2, varscan2
- POMP | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV101076797; called by muse, mutect2, varscan2
- POU2F1 | c.1541C>T p.P514L (on ENST00000541643 / NM_001365848.1; = p.P537L on NM_002697.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs780641145, COSV99610534; called by muse, mutect2, varscan2
- POU4F2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850340; called by muse, mutect2, varscan2
- PPFIA4 | c.3380C>T p.P1127L (on ENST00000447715; = p.P1128L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV55315957; called by muse, mutect2, varscan2
- PPID | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.433); catalogued as COSV100306727; called by muse, mutect2, varscan2
- PPP1R26 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.662); catalogued as COSV100778004; called by muse, mutect2, varscan2
- PPP2R1A | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100436084; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs540232176; called by mutect2, varscan2
- PRKDC | c.6248T>C p.L2083P | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100038726; called by muse, mutect2, varscan2
- PROX2 | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.591); catalogued as COSV101507793; called by muse, mutect2
- PRR5-ARHGAP8 | c.839C>T p.A280V (on ENST00000352766; = p.A157V on NM_181334.5) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as rs748242254, COSV100424018; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSMC3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1049340387, COSV100099325; called by muse, mutect2, varscan2
- PTPRK | c.2721del p.D908Ifs*13 (on ENST00000368215 / NM_001291984.2; = p.D909Ifs*13 on NM_002844.4) | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs763877925; called by mutect2, pindel, varscan2
- PXMP2 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527990964, COSV100443450; called by muse, mutect2, varscan2
- RAC3 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); catalogued as rs753178410, COSV100141709; called by muse, mutect2, varscan2
- RACK1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100958650; called by muse, mutect2, varscan2
- RAG1 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV100200701, COSV55023968; called by muse, mutect2, varscan2
- RASA2 | c.1049del p.L350* | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | catalogued as rs775275481; called by mutect2, varscan2
- RBM27 | c.591G>A p.E197= | Splice Region (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99505775; called by muse, mutect2, varscan2
- RBMS1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371387888, COSV62357650; called by muse, mutect2, varscan2
- RHD | c.784del p.Q262Kfs*26 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as COSV59646479; called by mutect2, pindel, varscan2
- RILPL1 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV100525954; called by muse, mutect2, varscan2
- RIMS3 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101013286; called by muse, mutect2, varscan2
- RLIM | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100222850; called by muse, mutect2, varscan2
- RNF213 | c.6825del p.K2276Sfs*14 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV100300684; called by mutect2, varscan2
- RNF40 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200311831; called by muse, mutect2, varscan2
- ROBO3 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1317777302, COSV101184941; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs752898741; called by mutect2, varscan2
- RPH3AL | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100046559; called by muse, mutect2, varscan2
- RPL18A | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs772151051, COSV99714368; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUFY4 | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100722953; called by muse, mutect2
- RXRA | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100709197; called by muse, mutect2, varscan2
- RYR2 | c.3295G>A p.G1099R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767849564, COSV100768381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMHD1 | c.1683G>T p.K561N (on ENST00000262878 / NM_001363729.2; = p.K596N on NM_015474.4) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV99455758; called by muse, mutect2, varscan2
- SATL1 | c.1154G>T p.G385V (on ENST00000395409; = p.G572V on NM_001012980.2) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1448488829, COSV100260686; called by muse, mutect2, varscan2
- SATL1 | c.703A>G p.S235G (on ENST00000395409; = p.S422G on NM_001012980.2) | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV100260687; called by muse, mutect2, varscan2
- SCFD2 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1402682368, COSV101189293; called by muse, mutect2, varscan2
- SEC23B | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV99357460; called by muse, mutect2, varscan2
- SEC31A | c.3409C>T p.P1137S (on ENST00000355196 / NM_001318120.1; = p.P1098S on NM_016211.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV100021618; called by muse, mutect2, varscan2
- SEPTIN14 | c.835T>C p.C279R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761901611, COSV101193221; called by muse, mutect2, varscan2
- SERPINE2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99296386; called by muse, mutect2, varscan2
- SFTPD | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100954482; called by muse, mutect2, varscan2
- SFTPD | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100954483; called by muse, mutect2, varscan2
- SH3KBP1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101114421; called by muse, mutect2, varscan2
- SHANK2 | c.3595G>A p.G1199R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs781993956, COSV99572533; called by muse, mutect2, varscan2
- SIGLEC1 | c.4595C>A p.P1532H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99163380; called by muse, mutect2, varscan2
- SKIV2L | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368453711; called by muse, mutect2, varscan2
- SLC12A1 | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV101118276; called by muse, mutect2, varscan2
- SLC13A5 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV99545737; called by muse, mutect2, varscan2
- SLC16A4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV100872909; called by muse, mutect2, varscan2
- SLC22A1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs760315741, COSV100266738, COSV61452511; called by muse, mutect2, varscan2
- SLC22A15 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1206235297, COSV65678826; called by muse, mutect2, varscan2
- SLC22A3 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1389851648, COSV99278412; called by muse, mutect2, varscan2
- SLC4A11 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs544270581, COSV101195904; called by muse, mutect2, varscan2
- SLC9A3R1 | c.444C>T p.R148= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as rs146791449, COSV99379862; called by muse, mutect2, varscan2
- SLCO2B1 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99214317; called by muse, mutect2, varscan2
- SMAD3 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100528775, COSV100528954; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCC1 | c.918+1G>A p.X306_splice | Splice Site (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99592382; called by muse, mutect2, varscan2
- SOCS5 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100125034; called by muse, mutect2, varscan2
- SPATA31A3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1447437015; called by mutect2, varscan2
- SPECC1 | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.784); catalogued as COSV99821366; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SSTR4 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1287108339, COSV54798438; called by muse, mutect2, varscan2
- STRIP2 | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV50808262, COSV99973512; called by muse, mutect2, varscan2
- STX16 | c.931A>G p.I311V (on ENST00000371141 / NM_001001433.3; = p.I290V on NM_003763.6) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs370017047; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNE2 | c.5728G>A p.V1910M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100646867; called by muse, mutect2, varscan2
- SYTL5 | c.446-1G>T p.X149_splice | Splice Site (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99936915; called by muse, mutect2, varscan2
- TADA1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs772749203, COSV100902294; called by muse, mutect2, varscan2
- TAF1 | c.1912G>T p.G638C (on ENST00000373790 / NM_138923.4; = p.G659C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334703; called by muse, mutect2, varscan2
- TAF10 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100196159; called by muse, mutect2, varscan2
- TAF6 | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100612629; called by muse, mutect2, varscan2
- TAS2R38 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1554444315, COSV101516352; called by muse, mutect2, varscan2
- TDRD1 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs906904597, COSV52589658; called by muse, mutect2, varscan2
- TEDC2 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV100709572; called by muse, mutect2, varscan2
- TENM1 | c.7779del p.R2594Gfs*15 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as COSV64442554; called by mutect2, pindel, varscan2
- TET2 | c.3015G>T p.K1005N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV99481396; called by mutect2, varscan2
- TEX264 | c.686T>C p.L229S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.273); catalogued as COSV99622506; called by muse, mutect2, varscan2
- TEX9 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV100771318; called by muse, mutect2, varscan2
- TGM4 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.401); catalogued as rs150203536; called by muse, mutect2, varscan2
- TGM4 | c.1777-1G>A p.X593_splice | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as COSV99942165; called by muse, mutect2, varscan2
- TLE1 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100918822; called by muse, mutect2, varscan2
- TMPRSS9 | c.2173del p.L725Wfs*16 (on ENST00000648592; = p.L691Wfs*16 on NM_182973.2) | Frame Shift Del (DEL) | VAF 25/43 reads (58%) | catalogued as rs762515337; called by mutect2, varscan2
- TNR | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV54910336, COSV99687976; called by muse, mutect2, varscan2
- TRERF1 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs751442173, COSV100550069; called by muse, mutect2, varscan2
- TRIB3 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99423649; called by muse, mutect2, varscan2
- TRIM46 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99825871; called by muse, mutect2, varscan2
- TRIM68 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1332950362, COSV100331635, COSV56169441; called by muse, mutect2, varscan2
- TRIO | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100709973; called by muse, mutect2, varscan2
- TSC2 | c.1622del p.P541Hfs*20 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as COSV54762148; called by mutect2, pindel, varscan2
- TSHZ3 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs201870186, COSV53666964, COSV99551825; called by muse, mutect2, varscan2
- TXN2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340374; called by muse, mutect2, varscan2
- TXNDC2 | c.1430C>A p.A477D (on ENST00000306084 / NM_001098529.2; = p.A410D on NM_032243.6) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100045793; called by muse, mutect2
- UAP1 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99617436; called by muse, mutect2, varscan2
- UPF3A | c.900_903del p.R301Efs*20 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs1342261002; called by pindel, varscan2
- UPK3B | c.511T>C p.C171R (on ENST00000257632; = p.C116R on NM_001347684.2) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as rs1191768786, COSV99990987; called by muse, mutect2, varscan2
- USP40 | c.2825A>G p.Q942R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99295854; called by muse, mutect2, varscan2
- USP47 | c.3031G>T p.E1011* (on ENST00000399455 / NM_001372095.1; = p.E923* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100359229; called by muse, mutect2, varscan2
- WDR27 | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV100358276; called by muse, mutect2, varscan2
- WDR7 | c.3412G>A p.G1138S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99588728; called by muse, mutect2, varscan2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs752097396; called by mutect2, varscan2
- WNK2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99941117; called by muse, mutect2, varscan2
- WNT5B | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs771391653, COSV60197501; called by muse, mutect2, varscan2
- XAB2 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV99349974; called by muse, mutect2, varscan2
- ZBP1 | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100473086; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF404 | c.1320A>T p.E440D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100182342; called by muse, mutect2, varscan2
- ZNF721 | c.2513C>T p.A838V (on ENST00000338977; = p.A850V on NM_133474.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1560222583, COSV100167088; called by muse, mutect2, varscan2
- ZNF780A | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776616074, COSV61815128; called by muse, mutect2, varscan2
- ZNF813 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs765661877, COSV67176175; called by muse, mutect2, varscan2
- A1BG | c.1347dup p.G450Rfs*94 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- ABCG8 | c.647dup p.E217* | Frame Shift Ins (INS) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- ACACA | c.4018A>G p.R1340G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACRBP | c.1100dup p.H368Tfs*9 | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by pindel, varscan2
- ADAM7 | c.101del p.K34Sfs*4 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.3365_3366del p.V1122Afs*76 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- ADAMTS17 | c.3121del p.R1041Afs*5 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- AGAP6 | c.918del p.E307Rfs*18 (on ENST00000374056 / NM_001365867.1; = p.E330Rfs*18 on NM_001077665.2) | Frame Shift Del (DEL) | VAF 54/145 reads (37%) | called by mutect2, varscan2
- AGO1 | c.49del p.L17Cfs*99 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ANKDD1A | c.652_661del p.L218Rfs*6 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- ANO10 | c.424del p.M142* | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.1858del p.S620Pfs*9 | Frame Shift Del (DEL) | VAF 63/94 reads (67%) | called by mutect2, pindel, varscan2
- ARID4A | c.3646del p.R1216Dfs*2 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- ASPA | c.244del p.M82Cfs*9 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- BTBD7 | c.479del p.L160Wfs*22 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CAPRIN2 | c.1602_1603del p.C534* | Nonsense Mutation (DEL) | VAF 48/111 reads (43%) | called by pindel, varscan2
- CC2D2A | c.4286del p.N1429Mfs*5 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- CCDC92 | c.698dup p.L233Ffs*18 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- CFAP298-TCP10L | c.246del p.K82Nfs*27 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- CNPY4 | c.224_225del p.R75Tfs*20 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by pindel, varscan2
- CYB5R3 | c.794del p.P265Qfs*8 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- DBR1 | c.641del p.L214* | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- F13A1 | c.468dup p.K157Efs*34 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- FLNA | c.7186dup p.E2396Gfs*8 (on ENST00000369850 / NM_001110556.2; = p.E2388Gfs*8 on NM_001456.3) | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- FLNA | c.4884del p.F1629Sfs*28 (on ENST00000369850 / NM_001110556.2; = p.F1629Sfs*35 on NM_001456.3) | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- GZMH | c.666del p.T224Hfs*16 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel
- HAND2 | c.381del p.N128Tfs*49 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- HMCN1 | c.6557dup p.N2186Kfs*16 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- IGHV4-59 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, varscan2
- IRF2 | c.500dup p.N167Kfs*2 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- JAK1 | c.2771dup p.E925Gfs*11 | Frame Shift Ins (INS) | VAF 32/85 reads (38%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580dup p.P861Tfs*4 | Frame Shift Ins (INS) | VAF 26/48 reads (54%) | called by mutect2, varscan2
- KIFBP | c.1516del p.I506* | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by mutect2, varscan2
- LAMB2 | c.2099del p.G700Efs*28 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.4779dup p.S1594Ifs*14 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- MPP7 | c.1669del p.T557Qfs*6 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- NAB2 | c.641del p.G214Efs*55 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- NARF | c.725del p.P242Lfs*13 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- OBSCN | c.16723del p.R5575Afs*40 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- OR2AT4 | c.646del p.L216Ffs*21 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- OR8H2 | c.896del p.N299Mfs*16 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- OSBPL10 | c.995del p.N332Mfs*14 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- P2RX3 | c.1048del p.A350Pfs*12 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.1970dup p.L658Afs*134 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- PIK3C3 | c.531+9del | Splice Region (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- PRG4 | c.3812del p.Y1271Lfs*18 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- PRKDC | c.7191_7194del p.C2397Wfs*11 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by pindel, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 42/66 reads (64%) | called by mutect2, pindel, varscan2
- PTEN | c.14_18del p.I5Rfs*4 | Frame Shift Del (DEL) | VAF 34/40 reads (85%) | called by mutect2, pindel, varscan2
- RIOK3 | c.306del p.K102Nfs*68 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | called by mutect2, varscan2
- RNF8 | c.1138_1140del p.E380del | In Frame Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- SAMD9 | c.4673del p.L1558* | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | called by mutect2, pindel, varscan2
- SCAF11 | c.3002del p.N1001Mfs*5 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- SERPINI1 | c.248del p.N83Mfs*8 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- SMG1 | c.9024del p.F3008Lfs*10 | Frame Shift Del (DEL) | VAF 27/57 reads (47%) | called by mutect2, pindel, varscan2
- SOX6 | c.878del p.P293Lfs*3 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- SRBD1 | c.2216del p.N739Mfs*10 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- SRGAP1 | c.168del p.A57Lfs*11 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- TRPM6 | c.5197_5200del p.F1733Qfs*5 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- UCN3 | c.54del p.R19Gfs*36 | Frame Shift Del (DEL) | VAF 26/53 reads (49%) | called by mutect2, pindel, varscan2
- XPNPEP2 | c.122del p.P41Lfs*38 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- ZNF292 | c.452del p.L151* | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- ZNF442 | c.658del p.W220Gfs*34 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- ABCA8 | c.3043C>T p.L1015= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99284992; called by muse, mutect2, varscan2
- ABCC1 | c.3360G>A p.P1120= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs748005412, COSV100578725; called by muse, mutect2, varscan2
- ADAMTS7 | c.849T>C p.I283= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV101183024; called by muse, mutect2, varscan2
- ADD1 | c.2103C>T p.A701= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs533175022, COSV99296065; called by muse, mutect2, varscan2
- ANKRD17 | c.7401C>T p.G2467= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100428632; called by muse, mutect2, varscan2
- APLP2 | c.1914C>T p.A638= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1362069978, COSV53839973; called by muse, mutect2, varscan2
- ARHGEF10L | c.957T>C p.H319= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs757680865, COSV99392117; called by muse, mutect2, varscan2
- ARHGEF2 | c.246C>A p.T82= (on ENST00000361247 / NM_001162383.2; = p.T55= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100560120; called by muse, mutect2, varscan2
- ATF7IP | c.3510C>T p.R1170= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs369961485; called by muse, mutect2, varscan2
- ATP2B3 | c.3627C>T p.P1209= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs781921289, COSV99683242; called by muse, mutect2, varscan2
- BRCA2 | c.8352G>A p.R2784= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs747664806, COSV101203978; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRD3 | c.627G>A p.T209= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs143863495; called by muse, mutect2, varscan2
- CA8 | c.570G>A p.Q190= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100526698, COSV100527094; called by muse, mutect2, varscan2
- CACNA1I | c.1263C>A p.S421= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100359393; called by muse, mutect2
- CACNB3 | c.951A>G p.V317= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99974717; called by muse, mutect2, varscan2
- CASZ1 | c.3120G>A p.A1040= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs1287151990, COSV100680775; called by muse, mutect2, varscan2
- CCR6 | c.180C>T p.G60= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100551000; called by muse, mutect2, varscan2
- CDH23 | c.3753C>T p.G1251= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs571842156, COSV56454718; called by muse, mutect2, varscan2
- CDH23 | c.8637C>T p.S2879= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs374552961; called by muse, mutect2, varscan2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CERKL | c.699C>T p.F233= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs375177042; called by muse, mutect2, varscan2
- CFAP100 | c.1698C>T p.R566= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs368437830; called by muse, mutect2, varscan2
- CLP1 | c.1179C>T p.D393= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100239756; called by muse, mutect2, varscan2
- COL13A1 | c.828C>G p.G276= (on ENST00000398978 / NM_001130103.2; = p.G219= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs777001080, COSV100637322, COSV62571648; called by muse, mutect2, varscan2
- CXCL17 | c.46C>T p.L16= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100544693; called by muse, mutect2
- DERL1 | c.705C>T p.G235= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs778081614, COSV52364706; called by muse, mutect2, varscan2
- DLGAP2 | c.990G>A p.A330= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1284127378, COSV101421075; called by muse, mutect2, varscan2
- DMPK | c.789G>A p.A263= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs754630789, COSV52182566; called by muse, mutect2, varscan2
- DOCK1 | c.2848T>C p.L950= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99727235; called by muse, mutect2, varscan2
- DRC7 | c.1131G>A p.G377= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV100395398; called by muse, mutect2, varscan2
- DSP | c.5937G>A p.Q1979= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV101131187; called by muse, mutect2, varscan2
- EAF1 | c.687C>A p.P229= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101112755; called by muse, mutect2, varscan2
- EHD3 | c.336C>T p.N112= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs146965464; called by muse, mutect2, varscan2
- EMILIN2 | c.2700T>G p.A900= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99598187; called by muse, mutect2, varscan2
- EPB41 | c.2427T>C p.G809= (on ENST00000343067 / NM_001166005.2; = p.G533= on NM_004437.4) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100548217; called by muse, mutect2, varscan2
- EPHB1 | c.1053G>A p.R351= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101212748; called by muse, mutect2, varscan2
- EXTL1 | c.1035G>A p.Q345= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100959060; called by muse, mutect2, varscan2
- FAM83H | c.3453G>T p.G1151= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs1240178858, COSV100567712; called by muse, mutect2, varscan2
- FLNC | c.2286C>T p.S762= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1160582987, COSV100367685; called by muse, mutect2, varscan2
- FSD1 | c.843G>T p.L281= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV55698219; called by muse, mutect2
- GALP | c.261T>C p.N87= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100627870; called by muse, mutect2, varscan2
- GAS6 | c.612G>T p.S204= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100581084, COSV100581382; called by muse, mutect2, varscan2
- GRM7 | c.174C>T p.H58= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100735847; called by muse, mutect2, varscan2
- GRM7 | c.2508G>A p.A836= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs750777601, COSV63171957; called by muse, mutect2, varscan2
- HDAC6 | c.273T>C p.D91= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100490612; called by muse, mutect2, varscan2
- HEATR1 | c.1578A>G p.L526= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100857487; called by muse, mutect2, varscan2
- HEATR5B | c.5793G>T p.V1931= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99248453; called by muse, mutect2, varscan2
- HERC1 | c.3525G>A p.T1175= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1314083175, COSV101496375; called by muse, mutect2, varscan2
- HIVEP3 | c.993A>C p.T331= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99911660; called by muse, mutect2, varscan2
- HMGN5 | c.180C>A p.A60= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1462069697, COSV63916442; called by muse, mutect2, varscan2
- HRNR | c.5376C>T p.T1792= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs1157494002; called by muse, mutect2, varscan2
- HS3ST1 | c.625C>T p.L209= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99136680; called by muse, mutect2, varscan2
- HSD3B2 | c.909A>G p.L303= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs757801056, COSV101027426; called by muse, mutect2, varscan2
- IGF2R | c.3369C>T p.S1123= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs781214253, COSV100806980; called by muse, mutect2, varscan2
- KCNH1 | c.1704C>T p.C568= (on ENST00000271751 / NM_172362.3; = p.C541= on NM_002238.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs749409939, COSV99657609; called by muse, varscan2
- KIAA1210 | c.930A>G p.R310= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV101273943; called by muse, mutect2, varscan2
- LCE1A | c.24G>A p.Q8= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV58727141; called by muse, mutect2, varscan2
- LCE1D | c.117C>T p.C39= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as COSV100405845; called by muse, mutect2, varscan2
- LPIN3 | c.1377G>A p.Q459= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100952907; called by muse, mutect2, varscan2
- LRRK1 | c.5502A>G p.S1834= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99438009; called by muse, mutect2, varscan2
- MARCHF1 | c.438G>A p.Q146= (on ENST00000274056; = p.Q129= on NM_017923.4) | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99920140; called by muse, mutect2, varscan2
- MICALL2 | c.927C>T p.T309= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs368474094; called by muse, mutect2, varscan2
- MMP9 | c.960C>T p.Y320= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs769437856, COSV63433733, COSV63434009; called by muse, mutect2, varscan2
- MTMR4 | c.699C>T p.C233= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100050811; called by muse, mutect2, varscan2
- MUC16 | c.26568G>T p.L8856= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV101198405; called by muse, mutect2, varscan2
- NFATC1 | c.246G>A p.P82= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs761575939, COSV99500733; called by muse, mutect2, varscan2
- NPHS1 | c.795C>T p.C265= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs779099247, COSV62286668; called by muse, mutect2, varscan2
- OR1C1 | c.240A>G p.Q80= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV101376191; called by muse, mutect2, varscan2
- PCDH8 | c.2787C>T p.S929= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV58810688; called by muse, mutect2, varscan2
- PDE6B | c.1752C>T p.D584= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99726983; called by muse, mutect2, varscan2
- PGLYRP4 | c.888C>A p.S296= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100668318; called by muse, mutect2, varscan2
- PRKACA | c.444G>A p.A148= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV58068240; called by muse, mutect2, varscan2
- PRKD1 | c.438C>T p.P146= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100119426; called by muse, mutect2, varscan2
- PSMD1 | c.2064C>A p.L688= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100433387; called by muse, mutect2, varscan2
- PYHIN1 | c.1014T>C p.N338= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV63722742; called by muse, mutect2, varscan2
- RAG1 | c.1092T>C p.N364= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100200702; called by muse, mutect2, varscan2
- RANGAP1 | c.1675C>T p.L559= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs868439558, COSV100663672; called by muse, mutect2, varscan2
- RIMS2 | c.4584C>T p.G1528= (on ENST00000666250 / NM_001348490.2; = p.G1099= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99163127; called by muse, mutect2, varscan2
- SASS6 | c.1320G>A p.E440= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99790637; called by muse, mutect2, varscan2
- SCO1 | c.252C>T p.S84= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99703491; called by muse, mutect2, varscan2
- SIAH3 | c.294C>T p.H98= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs773723798, COSV68552240; called by muse, mutect2, varscan2
- SLC22A3 | c.114C>A p.G38= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99278415; called by muse, mutect2, varscan2
- SLC26A11 | c.450C>A p.S150= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100413331; called by muse, mutect2, varscan2
- SLC26A5 | c.66C>A p.I22= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100098730, COSV59704540; called by muse, mutect2, varscan2
- SPAG16 | c.105G>A p.A35= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV55986814; called by muse, mutect2, varscan2
- SPPL2B | c.231C>T p.S77= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs369211000; called by muse, mutect2, varscan2
- SRD5A3 | c.835C>T p.L279= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs748009134, COSV99947995; called by muse, mutect2, varscan2
- TESK2 | c.1269C>T p.V423= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100517097; called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1399905400, COSV56405790; called by muse, varscan2
- TIAM1 | c.1314C>T p.G438= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99733176; called by muse, mutect2, varscan2
- TNNT3 | c.780C>T p.A260= (on ENST00000397301 / NM_001367846.1; = p.A249= on NM_006757.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs551410081, COSV99547969; called by muse, mutect2, varscan2
- TRRAP | c.5877G>A p.Q1959= (on ENST00000359863 / NM_001244580.1; = p.Q1941= on NM_003496.3) | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100722082; called by muse, mutect2, varscan2
- TSPAN16 | c.127C>T p.L43= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100368242; called by muse, mutect2, varscan2
- TTC6 | c.627C>T p.N209= (on ENST00000267368; = p.N1575= on NM_001310135.3) | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs762635328, COSV57450782; called by muse, varscan2
- TTC7A | c.396C>T p.Y132= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs780299149, COSV99766096; called by muse, mutect2, varscan2
- TXNL4A | c.78C>G p.V26= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99511379; called by muse, mutect2, varscan2
- UBR4 | c.2553G>A p.V851= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100920332; called by muse, mutect2, varscan2
- XPNPEP1 | c.1446C>T p.Y482= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs778274041, COSV100450826; called by muse, varscan2
- ZFPL1 | c.414T>C p.D138= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV99297693; called by muse, mutect2, varscan2
- ZNF155 | c.1419T>C p.N473= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99525529; called by muse, mutect2, varscan2
- ZNF197 | c.666G>A p.V222= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100482009; called by muse, mutect2, varscan2
- ZNF398 | c.1779C>T p.G593= (on ENST00000475153 / NM_170686.3; = p.G422= on NM_020781.4) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100246820; called by muse, mutect2, varscan2
- ZNF596 | c.525C>A p.A175= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100261531; called by muse, mutect2, varscan2
- ZNF646 | c.1881C>T p.R627= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100336414; called by muse, mutect2, varscan2
- ZZEF1 | c.6744G>A p.L2248= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV101067559; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850133 del T | 5'Flank (DEL) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1910T>C | RNA (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- MAPK3 | c.1017+50del | Intron (DEL) | VAF 7/23 reads (30%) | catalogued as rs1389475281, COSV99531111; called by pindel, varscan2
- PXN | c.831+1639G>A | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-572C>A | Intron (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100775623; called by muse, mutect2, varscan2
- SNORD116-4 | n.28del | RNA (DEL) | VAF 33/91 reads (36%) | catalogued as rs753149037; called by mutect2, pindel, varscan2
- TMPRSS11F | c.1015+1926A>G | Intron (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100678234; called by muse, mutect2, varscan2
